Somatic mutation profile of tumor specimen MBCProject_0564_T2_WES (aliquot MBCProject_0564_T2_WES_1) from CMI case MBCProject_0564, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.7 years (22,900 days).
Specimen MBCProject_0564_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d1479cd-1097-4e7a-919f-67b434be936a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0564_SALIVA (Saliva), aliquot MBCProject_0564_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c46ff02-e9f2-4684-a3f0-93dab94fc83e

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, 3'Flank 1, Splice Site 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.1504G>A p.D502N | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1422084838, COSV57422597; called by muse, mutect2
- AVPR1B | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs368239814; called by muse, mutect2
- CCIN | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV58724212; called by muse, mutect2, varscan2
- CDH1 | c.1008+1G>A p.X336_splice | Splice Site (SNP) | VAF 28/253 reads (11%) | catalogued as CS135588, COSV55728942; called by muse, mutect2, varscan2
- GRK2 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100419740; called by muse, mutect2
- GRPEL2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as COSV61387280, COSV61387406; called by muse, mutect2
- IHH | c.836C>T p.T279M | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs776499803, COSV55393314; called by muse, mutect2, varscan2
- MAP2K7 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1441304667, COSV67608310, COSV67609148; called by muse, mutect2, varscan2
- PLEC | c.1090G>A p.E364K (on ENST00000322810 / NM_201380.4; = p.E254K on NM_000445.5) | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554722122, COSV100517504; called by muse, mutect2
- TMPRSS11A | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs746187334; called by muse, mutect2
- CD244 | c.839G>A p.R280K (on ENST00000368033 / NM_001166663.2; = p.R275K on NM_016382.4) | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HEATR1 | c.3194G>A p.G1065E | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.88); called by muse, mutect2
- HMGB2 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2
- PDE10A | c.1574A>G p.H525R | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2
- SATB1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, mutect2
- GEN1 | c.2361G>A p.R787= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- OR14J1 | c.670C>T p.L224= | Silent (SNP) | VAF 14/237 reads (6%) | called by muse, mutect2
- ATRX | c.5567-41T>C | Intron (SNP) | VAF 12/146 reads (8%) | catalogued as rs3027549; called by muse, mutect2
- HRH2 | chr5:175685482 del T | 3'Flank (DEL) | VAF 12/108 reads (11%) | called by mutect2, varscan2
- SCAMP4 | c.-10T>C | 5'UTR (SNP) | VAF 18/293 reads (6%) | called by muse, mutect2
